Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4765, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4765-01A (Primary Tumor).

[page 1 of 2]
...

Clinical Diagnosis & History:

Right renal mass.

Specimens Submitted:

1: SP: Right renal mass

2: SP: Right perirenal fat

DIAGNOSIS:

- 1) KIDNEY, RIGHT; PARTIAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL CLEAR CELL TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS ACINAR.
- THE TUMOR GREATEST DIAMETER IS 3.2 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- 2) SOFT TISSUE, PERIRENAL, RIGHT; EXCISION:
- BENIGN ADIPOSE TISSUE.
- [REDACTED]
- [REDACTED]

1) The specimen is received fresh for frozen, labeled "Right renal mass". It consists of a portion of renal cortex measuring 4.5 x 3.5 x 0.8 cm with a well-circumscribed soft yellow-tan and hemorrhagic tumor measuring 3.2 x 2.5 x 2.5 cm and an attached piece of perirenal fat measuring 5.0 x 5.0 x 1.0 cm. The tumor is 0.2 cm away from the inked surgical margins. Portion of the tissue is submitted for frozen section. Representative sections are submitted for histologic examination.

Summary of Sections:

FSC - frozen section control

T - tumor

[REDACTED]

2) The specimen is received in formalin, labeled "Right perirenal fat". It consists of multiple irregular yellow-tan lobulated fragments of adipose tissue measuring 12.5 x 8.5 x 2.0 cm in aggregate. Sectioning reveals no gross histologic abnormalities. Representative sections submitted for histologic examination en bloc.

Summary of Sections:

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

U - undesignated

Summary of Sections:

Part 1: SP: Right renal mass [REDACTED]

Block	Sect. Site	PCs
1	fsc	1
5	rs	5
3	t	3

Part 2: SP: Right perirenal fat [REDACTED]

Block	Sect. Site	PCs
1	u	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: DEEP MARGIN NEGATIVE FOR TUMOR. RENAL CELL CARCINOMA. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- [REDACTED]

Source: NCI Genomic Data Commons file c3067d0c-c5bf-45f4-ad4a-f4919099a734 (TCGA-BP-4765.E2E3BDFA-CE94-48C6-937C-75CF042CBE59.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).